Gene-level copy-number profile of tumor specimen ALCH-ADHM-TTP1-A from ALCHEMIST case ALCH-ADHM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 37.6 years (13,746 days).
Specimen ALCH-ADHM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f5b2ff8-9a36-4f3b-8e10-6460c199be1c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADHM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/367e005a-c300-40a2-978a-ad6a74e4f327

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,086; copy number 2: 55,248; copy number 3: 519; copy number 4: 17; copy number 5: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:27,106,184–27,158,976, 10 genes, copy number 5: HOXA3, HOXA-AS2, HOXA4, AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4.
- chr16:32,869,985–32,873,128, 1 gene, copy number 5: BCAP31P2.

Autosomal genes at a single copy (total copy number 1): 230. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
